Somatic mutation profile of tumor specimen HCM-BROD-0195-C71-01A (aliquot HCM-BROD-0195-C71-01A-21D-A786-36) from HCMI case HCM-BROD-0195-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,260 days).
Specimen HCM-BROD-0195-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9a106b-7c16-4f34-b200-cfd59fb4b4fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0195-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0195-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e486ad5-521b-424b-9837-b6057acb0f61

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 7, Intron 5, 3'UTR 3, Nonsense Mutation 2, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 87/153 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 350/466 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFP | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.795); catalogued as COSV99890117; called by muse, mutect2, varscan2
- BCOR | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 34/712 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs374493655, COSV60708344; called by muse, mutect2
- CT47B1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 251/673 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1465740235, COSV64890358, COSV64890667; called by muse, mutect2, varscan2
- ITIH2 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs199888149, COSV100623341; called by muse, mutect2, varscan2
- MUC2 | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.33); catalogued as rs542457432; called by muse, mutect2, varscan2
- NLRP11 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs751156777, COSV64085872; called by muse, mutect2, varscan2
- OR4S1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs777534434, COSV60679707; called by muse, mutect2, varscan2
- PKD1L1 | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as COSV56976848; called by muse, mutect2
- SLCO6A1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.071); catalogued as COSV65808025; called by muse, mutect2
- TNKS | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs769744588; called by muse, mutect2, varscan2
- TNNI1 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs372956100; called by muse, mutect2, varscan2
- TRPV5 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 154/514 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs765394613; called by muse, mutect2, varscan2
- ZFYVE28 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 29/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779826543, COSV52118452; called by muse, mutect2
- ZNF469 | c.5701G>A p.A1901T (on ENST00000437464; = p.A1929T on NM_001367624.2) | Missense Mutation (SNP) | VAF 114/457 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.101); catalogued as rs1249651303; called by muse, mutect2, varscan2
- ABCD1 | c.1725C>A p.D575E | Missense Mutation (SNP) | VAF 113/679 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AC231657.3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 287/800 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BTK | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 160/407 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPNS2 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLDN34 | c.236A>T p.D79V | Missense Mutation (SNP) | VAF 166/430 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CRYZL1 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DDX56 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DOCK8 | c.906_950del p.N302_R317delinsK | In Frame Del (DEL) | VAF 90/406 reads (22%) | called by mutect2, pindel
- FAM9A | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FLG | c.320A>T p.H107L | Missense Mutation (SNP) | VAF 133/763 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAP3K19 | c.3784A>C p.T1262P | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCL | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NUP153 | c.2903A>G p.K968R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2
- PPEF2 | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | called by muse, mutect2, varscan2
- SCUBE3 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZHX3 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- C8A | c.573C>T p.D191= | Silent (SNP) | VAF 120/297 reads (40%) | called by muse, varscan2
- CAT | c.891C>T p.F297= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs373984976; called by muse, mutect2, varscan2
- KCNT1 | c.1620C>T p.N540= (on ENST00000488444; = p.N559= on NM_020822.3) | Silent (SNP) | VAF 64/156 reads (41%) | catalogued as rs1028802868; called by muse, mutect2, varscan2
- MAP7D3 | c.2403G>A p.E801= | Silent (SNP) | VAF 132/373 reads (35%) | called by muse, mutect2, varscan2
- OBSCN | c.19923C>T p.S6641= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as rs144111673; called by muse, mutect2, varscan2
- PRKACA | c.441C>T p.Y147= | Silent (SNP) | VAF 99/227 reads (44%) | catalogued as rs558688172, COSV58067130, COSV58070627; called by muse, mutect2, varscan2
- PSG8 | c.417C>A p.T139= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- ADGRE3 | c.*45T>A | 3'UTR (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- AL353804.4 | chrX:73823938 A>C | 5'Flank (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- ATP11C | c.3297+166T>A | Intron (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- BOD1P2 | n.239C>T | RNA (SNP) | VAF 50/110 reads (45%) | catalogued as rs1163498443; called by muse, mutect2, varscan2
- C17orf99 | c.640+37C>T | Intron (SNP) | VAF 50/387 reads (13%) | catalogued as rs368298191; called by muse, mutect2, varscan2
- GATA1 | c.*49G>C | 3'UTR (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2268C>T | Intron (SNP) | VAF 56/768 reads (7%) | catalogued as rs773318472; called by muse, mutect2
- PHF19 | c.465+19C>T | Intron (SNP) | VAF 288/718 reads (40%) | catalogued as COSV100384269; called by muse, mutect2, varscan2
- RTN4RL2 | c.513+516C>G | Intron (SNP) | VAF 59/142 reads (42%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.*790_*794del | 3'UTR (DEL) | VAF 92/292 reads (32%) | catalogued as rs1265368763; called by pindel, varscan2
